Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GC, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GC-01A (Primary Tumor).

[page 1 of 3]
Subject ID

GROSS:

Specimen status: Received in fresh

Operation: Distal gastrectomy

Organ:

Stomach (great curvature: 18.5 cm, lesser curvature, 11.0 cm,
proximal resection margin: 14.0 cm, distal resection margin, 6.5 cm)
Duodenum (1.7 cm in greatest dimension)

Lesion:

An ill defined ulcerofungating mass (4.0 x 4.0 x 1.2 cm) in antrum

Tumor location: Middle 1/3 (antrum), lesser curvature

From proximal resection margin - 2.5 cm

From distal resection margin - 4.0 cm

Gross serosal invasion: Yes

Gross photo: Present

Block

T1-5, TB, tumor and surrounding tissue x 6

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin x 1

D, DRM, distal resection margin x 2

LN1, superior gastric lymph nodes x 1

LN2-3, inferior gastric lymph nodes x 2

LN4, lymph nodes labelled as '1' x 1

LN5, lymph nodes labelled as '4sb' x 1

LN6, lymph nodes labelled as '5' x 1

LN7, lymph nodes labelled as '6' x 1

LN8, lymph nodes labelled as '7' x 1

LN9, lymph nodes labelled as '8' x 1

LN10-11, lymph nodes labelled as '9' x 2

LN12, lymph nodes labelled as '11p' x 1

LN13, lymph nodes labelled as '12' x 1

ICD-0-3
adenocarcinoma, diffuse type 8145/3
Site: stomach, antrum C16.3
fw 9/27/12

MICROSCOPIC

<WHO histologic typing>

Adenocarcinoma, tubular, poorly differentiated

Depth of invasion:

[page 2 of 3]
T4a-Tumor penetration of serosa

Margins:

Proximal resection margin: Uninvolved

Distal resection margin: Uninvolved

Ming (Growth pattern) classification: Infiltrative

Lymphoid reaction: Absent

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Present

Polyps: No

Lymph node metastasis: Present

Distant metastasis: Cannot be assessed

Pathologic stage: pT4aN2Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, lesser curvature, antrum, distal gastrectomy:

Adenocarcinoma, poorly differentiated, infiltrating

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type

Lymph node, perigastric, distal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (1/5)

Inferior gastric: Metastatic carcinoma, primary in stomach (2/6)

Lymph node, regional, excision:

Labeled '1': No tumor present (0/1)

Labeled '4sb': No tumor present (0/2)

Labeled '5': No tumor present (0/2)

Labeled '6': No tumor present (0/1)

Labeled '7': No tumor present (0/2)

Labeled '8': No tumor present (0/1)

Labeled '9': No tumor present (0/9)

Labeled '11p': No tumor present (0/14)

Labeled '12': No lymphoid tissue

Dual/Synchronous Primary		NOTED

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form, completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In the original pathology report, this tumor is described as Lauren intestinal type. Review of TCGA sample top slide identified this tumor as Lauren diffuse type and poorly-differentiated	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 6e600ef2-6062-416b-b3e0-55cb139e3df1 (TCGA-HU-A4GC.AA11FCA0-1836-4655-989E-41B729499E37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).